Gene-level copy-number profile of tumor specimen TCGA-DK-A6AV-01A from TCGA case TCGA-DK-A6AV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 82.4 years (30,089 days).
Specimen TCGA-DK-A6AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6848256c-4433-4575-abe5-cd59f45de5ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A6AV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0d1b03f-5ec1-4d59-8405-2374e390a0b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 794; copy number 2: 20,574; copy number 3: 14,103; copy number 4: 8,274; copy number 5: 9,689; copy number 6: 5,982; copy number 7: 52; copy number 8: 64; copy number 10: 72; copy number 11: 94; copy number 18: 46; copy number 19: 21; copy number 25: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A6AV-01A-12D-A30D-01): tumor purity 0.5, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,429,901–120,179,119, 9 genes (within-gene range 0–2): TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5.
- chr6:70,566,917–70,862,011, 7 genes (within-gene range 0–2): SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1.
- chr18:44,214,971–44,342,315, 1 gene (within-gene range 0–2): AC110014.1.
- chr18:44,320,800–44,322,257, 1 gene: KRT8P5.
- chr18:71,732,615–71,944,577, 4 genes: LINC01899, AC027458.1, AC069114.1, AC069114.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15,479 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–121,580,524, 2,865 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–92,035,000, 1,642 genes, copy number 6 (broad region; genes not listed).
- chr3:11,745–45,160,175, 684 genes, copy number 5–6 (broad region; genes not listed).
- chr3:58,717,365–66,637,412, 74 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:69,054,730–198,222,513, 1,999 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr4:49,096–27,025,381, 475 genes, copy number 5 (broad region; genes not listed).
- chr4:46,993,723–55,947,996, 134 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:58,198–26,013,025, 416 genes, copy number 6–8 (broad region; genes not listed).
- chr5:26,473,505–45,895,970, 293 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:70,972–57,275,197, 1,049 genes, copy number 6 (broad region; genes not listed).
- chr8:50,762,460–59,893,942, 137 genes, copy number 5 (broad region; genes not listed).
- chr8:97,144,170–103,501,895, 162 genes, copy number 5–6 (broad region; genes not listed).
- chr8:103,559,099–103,769,029, 3 genes, copy number 6: PTMAP15, AC007751.1, AC090686.1.
- chr8:104,566,086–145,066,685, 593 genes, copy number 5 (broad region; genes not listed).
- chr10:5,364,966–11,336,675, 97 genes, copy number 18–25 (within-gene range 2–25) (broad region; genes not listed).
- chr11:66,975,277–70,021,059, 118 genes, copy number 5–10 (broad region; genes not listed).
- chr12:12,891,559–56,163,496, 975 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:56,266,890–104,350,307, 836 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr16:67,893,254–69,941,741, 95 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr17:72,627,231–73,312,005, 17 genes, copy number 6: RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.
- chr18:2,916,994–3,013,144, 1 gene, copy number 5 (within-gene range 2–5): LPIN2.
- chr18:2,948,238–4,455,307, 32 genes, copy number 5 (within-gene range 2–5): AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr19:22,902,538–29,213,151, 87 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:30,553,956–58,605,223, 1,622 genes, copy number 6–7 (broad region; genes not listed).
- chr20:28,563,850–39,663,552, 318 genes, copy number 6 (broad region; genes not listed).
- chr20:41,024,205–64,313,132, 591 genes, copy number 6 (broad region; genes not listed).
- chr21:10,328,411–22,884,000, 164 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 794. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
